Somatic mutation profile of tumor specimen 0DGZFD from CCDI case PBBSEW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 12.9 years (4,715 days).
Specimen 0DGZFD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8ab1ea6-cbc9-4dc2-ab26-941ecf3bcb03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGYZ4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/163f831c-867c-4734-88b1-5629b1cbf940

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 2, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZSCAN10 | c.955C>T p.R319C (on ENST00000252463; = p.R374C on NM_032805.3) | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs772666527, COSV52967602; called by muse, mutect2, varscan2
- MDFIC | c.52G>C p.V18L | Missense Mutation (SNP) | VAF 98/442 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- RALGAPA1 | c.4799G>A p.R1600H | Missense Mutation (SNP) | VAF 22/805 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPDYA | c.49T>A p.Y17N | Missense Mutation (SNP) | VAF 106/1338 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2
- TRPC4 | c.1811A>G p.Y604C | Missense Mutation (SNP) | VAF 194/1514 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DENR | c.*98A>G | 3'UTR (SNP) | VAF 20/212 reads (9%) | called by muse, mutect2
- FCHO2 | c.1173+13A>G | Intron (SNP) | VAF 20/546 reads (4%) | called by muse, mutect2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- SKIDA1 | c.-61T>C | 5'UTR (SNP) | VAF 9/242 reads (4%) | catalogued as rs1015442172; called by muse, mutect2
